Surgical pathology report (de-identified scan), TCGA case TCGA-61-2610, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-2610-01A (Primary Tumor).

FINAL DIAGNOSIS:

FINAL DIAGNOSIS:

- METASTATIC POORLY DIFFERENTIATED PAPILLARY SEROUS CARCINOMA OF OMENTUM
- METASTATIC PAPILLARY SEROUS CARCINOMA INVOLVING SEROSA AND MUSCULARIS OF SMALL BOWEL
- METASTATIC POORLY DIFFERENTIATED PAPILLARY SEROUS CARCINOMA INVOLVING VERMIFORM APPENDIX
- C) METASTATIC POORLY DIFFERENTIATED SEROUS PAPILLARY CARCINOMA OF RIGHT OVARY AND RIGHT FALLOPIAN TUBE
- D) POORLY DIFFERENTIATED PAPILLARY SEROUS CARCINOMA OF LEFT OVARY
- METASTATIC POORLY DIFFERENTIATED PAPILLARY SEROUS CARCINOMA OF LEFT FALLOPIAN TUBE
- E) UTERUS WITHOUT ADNEXA, 70 GRAMS:
- METASTATIC POORLY DIFFERENTIATED PAPILLARY SEROUS CARCINOMA INVOLVING CERVIX, ENDOMETRIUM, MYOMETRIUM AND UTERINE SEROSA
- CHRONIC CERVICITIS WITH SQUAMOUS METAPLASIA
- INACTIVE ENDOMETRIUM

FINAL DIAGNOSIS:

FINAL DIAGNOSIS:

PREVIOUS REPORTS:

- A) NODULE, SMALL BOWEL MESENTERY:
- FAT NECROSIS, FIBROSIS AND REACTIVE CHANGES, NEGATIVE FOR TUMOR
- B,C,CFS1&2) CYST, MID WALL PELVIS:
- METASTATIC POORLY DIFFERENTIATED ADENOCARCINOMA CONSISTENT WITH OVARIAN PRIMARY
- D,DFS) PORTION DESCENDING COLON:
- METASTATIC POORLY DIFFERENTIATED ADENOCARCINOMA INVOLVING SEROSA AND MUSCULARIS OF LARGE BOWEL
- SURGICAL MARGINS OF RESECTION, NEGATIVE FOR TUMOR
- FOUR (4) MESENTERIC LYMPH NODES, NEGATIVE FOR TUMOR (0/4)

Source: NCI Genomic Data Commons file 8076ba1d-5173-466b-82df-9b156cc0e856 (TCGA-61-2610.A5914371-94AB-4079-A6EA-11C79E9DB4A1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).